Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A7M4, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A7M4-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

CONFIDENTIAL

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Report Patient

Name

Demographics (for

verification purposes)

Date of Birth:

Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Specimen Description

Pancreas and spleen, part of left adrenal,

Clinical Information

Pancreatic mass.

Diagnosis

Pancreas, Spleen, and Portion of (Left Adrenal), Resection:

Invasive poorly differentiated invasive ductal adenocarcinoma of the
pancreas (see synoptic report for details).

Reported by:

Electronically signed by:

Verified:

Synoptic Report

SPECIMEN:

Body of pancreas

Tail of pancreas

Spleen

Portion of adrenal

PROCEDURE:

Partial pancreatectomy, pancreatic body

TUMOR SITE:

Pancreatic body

TUMOR SIZE:

Greatest dimension: 3.6 cm

Additional dimensions: 3.0 x 2.3 cm

ICD-O-3
Adenocarcinoma, duct NOS
8500/3
Site Pancreas body C25.1
JW 10/10/13

[page 2 of 3]
HISTOLOGIC TYPE:
Ductal adenocarcinoma
HISTOLOGIC GRADE:
G3: Poorly differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades peripancreatic soft tissues
Tumor invades retroperitoneal soft tissue
MARGINS:

Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 0.4 mm
Specified margin: Retroperitoneal
Invasive carcinoma involves posterior retroperitoneal surface of pancreas
TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):
Not known
LYMPH-VASCULAR INVASION:
Present
PERINEURAL INVASION:
Not identified
PRIMARY TUMOR (pT):
pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
REGIONAL LYMPH NODES (pN):
pN1: Regional lymph node metastasis
Number examined: 16
Number involved: 1
ANCILLARY STUDIES:
IHC: VIM+, CTK19+, B34E12+, CEAp weakly +, calretinin weakly +, inhibin -
COMMENT(S):
The one positive lymph node is involved by direct extension

Gross Description
Received is a single specimen container. The requisition and specimen container are
labelled with the patient's name. The cassette and are
labelled with the .

Specimen is received fresh. The container is designated "pancreas and spleen, part of left adrenal". The specimen consists of a partial pancreatectomy and splenectomy specimen measuring 16.0 x 12.5 x 7.0 cm. The spleen measures 12.5 x 6.5 x 6.5 cm and has a smooth capsule. On sectioning, the spleen is congested but no focal lesion are identified. The pancreatic portion measures 11.5 x 5.5 x 4.5 cm. The proximal resection margin is inked black. The superior margin is inked blue and the inferior portion is inked green. On sectioning, arising in the mid-body of the pancreas is a firm infiltrative white/grey mass measuring 3.0 x 3.6 x 2.3 cm. The tumor does appear to extend out beyond the pancreas proper. Foci of cystic change and necrosis are seen. The tumor is located 3.5 cm from the proximal resection margin. It extends to within 0.3 cm of the inferior portion and 0.4 cm of the superior portion. Note that in the midportion of the specimen, a piece of adrenal gland tissue is identified, measuring 2.0 x 2.5 x 1.3 cm. The pancreatic mass is in direct juxtaposition to the adrenal gland. The surrounding pancreas is otherwise unremarkable.

- A1 spleen
- A2 splenic hilum
- A3 proximal margin (shave margin)
- A4-A5 tumor with adrenal
- A6 tumor and inferior border
- A7 tumor and superior border
- A8-A9 additional tumor
- A10 non-neoplastic pancreas
- A11-A15 potential lymph nodes

[page 3 of 3]
Pathologist Comment

Although grossly it appeared as though adrenal tissue was present, this could not be confirmed with certainty on histology. Numerous pigment laden cells with an epithelioid morphology were identified adjacent to the tumor, but these are believed to represent macrophages rather than adrenal cortical cells.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 4b053b27-4afa-4bec-a9a2-66fb73630e24 (TCGA-IB-A7M4.84520A5B-EE82-4913-909A-851C3886F20C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).